Gene-level copy-number profile of tumor specimen TCGA-EF-5831-01A from TCGA case TCGA-EF-5831, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 72.1 years (26,331 days).
Specimen TCGA-EF-5831-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.d7680348-0c80-48c8-8279-70b6135a94bc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EF-5831-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/df5acde0-3655-4b62-b675-f1bae2eb17b8

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,350; copy number 2: 16,628; copy number 3: 27,593; copy number 4: 10,185; copy number 5: 1,922; copy number 6: 1,494; copy number 7: 632; copy number 9: 5; copy number 15: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-EF-5831-01): tumor purity 0.63, ploidy 3.11, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 639 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:18,467,172–47,307,301, 574 genes, copy number 7 (broad region; genes not listed).
- chr17:51,260,546–53,106,358, 12 genes, copy number 7 (within-gene range 4–7): UTP18, LINC02071, AC005823.2, AC005823.1, LINC02073, RPL7P48, CA10, AC002090.1, LINC01982, LINC02089, LINC02876, MTCO1P40.
- chr17:53,353,427–53,439,721, 3 genes, copy number 7: AC005341.1, AC090079.1, AC090079.2.
- chr17:65,100,812–65,227,703, 2 genes, copy number 7: RGS9, AC060771.1.
- chr17:65,635,537–66,192,133, 1 gene, copy number 7 (within-gene range 4–7): CEP112.
- chr17:68,974,488–72,644,490, 45 genes, copy number 7–9 (within-gene range 4–9): ABCA9, ABCA6, SEC24AP1, MIR4524B, MIR4524A, ABCA10, PRO1804, AC005495.1, ABCA5, SNRPGP4, AC115085.1, MAP2K6, AC015920.1, AC002546.1, LINC01483, AC002545.1, LINC01497, Y_RNA, AC005208.1, LINC01028, KCNJ16, KCNJ2-AS1, KCNJ2, CALM2P1, AC011990.1, AC005771.1, AC007423.1, AC005181.1, CASC17, RNU7-155P, AC118653.1, MYL6P5, AC007432.1, AC005144.1, ROCR, LINC01152, AC007461.1, SOX9-AS1, LINC02097, SOX9, LINC00511, LINC02003, AC007639.1, RPL32P33, AC080037.2.
- chr18:24,321,686–24,367,984, 2 genes, copy number 15: MIR320C2, AC023983.1.

Autosomal genes at a single copy (total copy number 1): 1,350. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
